Somatic mutation profile of tumor specimen C3L-06228-01 (aliquot CPT0477130006) from CPTAC case C3L-06228, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 63.3 years (23,127 days).
Specimen C3L-06228-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b91d1d4d-d2a0-4c20-b341-9c5b34af046a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06228-32 (Blood Derived Normal), aliquot CPT0475560005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa1ec204-1338-4daf-a60e-149be5fef501

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 41/318 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.6401G>T p.S2134I | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs758621975; called by muse, mutect2
- CCER2 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 58/670 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs572515560; called by muse, mutect2
- DOCK10 | c.3530C>A p.A1177D | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs1369871656; called by muse, mutect2
- EXD3 | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs370376781; called by muse, mutect2, varscan2
- HYDIN | c.6959G>A p.R2320Q | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs752976886; called by muse, mutect2
- MYPOP | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs1460780943; called by muse, mutect2, varscan2
- NAPG | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV100529948; called by muse, mutect2, varscan2
- NOS1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs773623606, COSV57607832; called by muse, mutect2
- OR6K6 | c.749T>C p.I250T (on ENST00000368144; = p.I226T on NM_001005184.1) | Missense Mutation (SNP) | VAF 28/435 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs780594211; called by muse, mutect2
- PALLD | c.1046C>G p.P349R | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.959); catalogued as COSV54974488; called by muse, mutect2
- PCDHA7 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 47/367 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV65337231; called by muse, mutect2, varscan2
- PDZD7 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs1408396864; ClinVar: uncertain significance; called by muse, mutect2
- VWF | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs61748491, CM070308, COSV54624744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF420 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58492580; called by muse, mutect2, varscan2
- ZNF772 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs781098749, COSV58411681; called by muse, mutect2
- CD37 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- ITGAV | c.2550G>T p.M850I | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.134); called by muse, mutect2
- KMT2D | c.13000G>T p.A4334S | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2
- LPIN3 | c.415A>C p.T139P | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.1); called by muse, mutect2
- PCED1A | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2
- PNPLA3 | c.708G>C p.E236D | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- POLR2B | c.3347T>G p.V1116G | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2
- PPIAL4A | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PPP3CB | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TERB1 | c.1464T>A p.D488E | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS12 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- TRO | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCY1 | c.1413C>T p.I471= | Silent (SNP) | VAF 17/316 reads (5%) | catalogued as rs780254994, COSV52033436; called by muse, mutect2
- BAHCC1 | c.561C>T p.A187= | Silent (SNP) | VAF 63/472 reads (13%) | catalogued as rs1403340863; called by muse, mutect2, varscan2
- CREB5 | c.1113C>T p.D371= (on ENST00000357727 / NM_182898.4; = p.D364= on NM_004904.3) | Silent (SNP) | VAF 23/432 reads (5%) | catalogued as rs765684376, COSV100744529; called by muse, mutect2
- F8 | c.6288A>C p.A2096= | Silent (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- FLG | c.7293C>T p.T2431= | Silent (SNP) | VAF 61/474 reads (13%) | catalogued as rs760670220, COSV64238667; called by muse, mutect2, varscan2
- GNAS | c.66C>T p.I22= | Silent (SNP) | VAF 20/347 reads (6%) | catalogued as rs757329603; called by muse, mutect2
- HOXB4 | c.336G>A p.A112= | Silent (SNP) | VAF 57/391 reads (15%) | called by muse, mutect2, varscan2
- KLHL34 | c.1785C>T p.Y595= | Silent (SNP) | VAF 17/273 reads (6%) | catalogued as COSV101069952; called by muse, mutect2
- LCK | c.1357C>T p.L453= | Silent (SNP) | VAF 28/348 reads (8%) | catalogued as rs200540406; called by muse, mutect2
- MARS1 | c.2472G>T p.T824= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- PXDN | c.1893G>A p.A631= | Silent (SNP) | VAF 16/334 reads (5%) | catalogued as rs375951000; called by muse, mutect2
- SYNE2 | c.4047T>C p.D1349= | Silent (SNP) | VAF 44/322 reads (14%) | called by muse, mutect2, varscan2
- TM7SF3 | c.1164G>A p.S388= | Silent (SNP) | VAF 22/350 reads (6%) | catalogued as rs139964818; called by muse, mutect2
- TMEM273 | c.249G>A p.P83= | Silent (SNP) | VAF 36/431 reads (8%) | catalogued as rs202171289, COSV65152736; called by muse, mutect2
- ZNF512B | c.2208G>A p.L736= | Silent (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- KCNQ1 | c.1514+28413G>A | Intron (SNP) | VAF 16/282 reads (6%) | catalogued as rs1258765759; called by muse, mutect2
- NRG3 | c.823+1838G>T | Intron (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
